Somatic mutation profile of tumor specimen TCGA-06-0158-01A (aliquot TCGA-06-0158-01A-01D-1491-08) from TCGA case TCGA-06-0158, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.5 years (26,856 days).
Specimen TCGA-06-0158-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 401a5237-39f0-4dd2-9c7f-f9c7e0e24aea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0158-10A (Blood Derived Normal), aliquot TCGA-06-0158-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b77d6cc4-83b0-4292-9e17-3b93be126eed

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Splice Region 3, Frame Shift Del 1, Nonsense Mutation 1, 3'Flank 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 194/2780 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2
- ITGB2 | c.897+1G>A p.X299_splice | Splice Site (SNP) | VAF 41/123 reads (33%) | catalogued as rs201752283, CS1513870, CS151558, CS920765, COSV56610868; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACBD3 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.444); catalogued as COSV64730503; called by muse, mutect2, varscan2
- ADAM29 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs544557652, COSV63662285; called by muse, mutect2
- AMBN | c.419T>A p.L140Q | Missense Mutation (SNP) | VAF 129/322 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59826749; called by muse, mutect2, varscan2
- ANO5 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs199532484, CM137911, COSV61084245; called by muse, mutect2, varscan2
- ANXA8L1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.175); catalogued as rs1554975591, COSV63225737; called by muse, mutect2, varscan2
- APOF | c.238G>C p.A80P | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.161); catalogued as COSV58476019; called by muse, mutect2, varscan2
- ASB15 | c.1596G>A p.E532= | Splice Region (SNP) | VAF 70/182 reads (38%) | catalogued as COSV51926792; called by muse, mutect2, varscan2
- CANT1 | c.1194C>G p.I398M | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV56605783; called by muse, mutect2, varscan2
- CATIP | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369378162; called by muse, mutect2, varscan2
- CCR8 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 168/380 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs765041382, COSV100413117, COSV58336997; called by muse, varscan2
- CFAP77 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV58012494; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2858C>G p.A953G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52111059; called by muse, mutect2, varscan2
- CR2 | c.2048C>T p.T683M | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.118); catalogued as rs766120010, COSV65508163; called by muse, mutect2, varscan2
- CRISP3 | c.168T>C p.D56= (on ENST00000371159 / NM_001368123.1; = p.D38= on NM_006061.4) | Splice Region (SNP) | VAF 143/366 reads (39%) | catalogued as COSV53821054; called by muse, mutect2, varscan2
- EDIL3 | c.357C>T p.N119= | Splice Region (SNP) | VAF 73/211 reads (35%) | catalogued as rs1405487502, COSV56903130; called by muse, mutect2, varscan2
- KCNH8 | c.2854A>T p.S952C | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV60466989; called by muse, mutect2, varscan2
- KRBA2 | c.151A>C p.N51H | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.245); catalogued as COSV58779284; called by muse, mutect2, varscan2
- LY9 | c.848T>G p.L283W | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV54434948; called by muse, mutect2, varscan2
- MC3R | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs775292393, COSV54763666; called by muse, mutect2, varscan2
- NAALAD2 | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV58962048; called by muse, mutect2, varscan2
- NLRP11 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV64087848; called by muse, mutect2, varscan2
- NUP205 | c.3392G>A p.R1131H | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV53660852; called by muse, mutect2, varscan2
- ODF3L2 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs753944829, COSV52743791; called by muse, mutect2, varscan2
- OR13G1 | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV62944483; called by muse, varscan2
- OR2L8 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs565612069, COSV100594400, COSV61727112; called by muse, mutect2, varscan2
- PCDHGA10 | c.1765G>A p.G589S | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as rs749356512, COSV53967783; called by muse, mutect2, varscan2
- PIAS4 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 18/459 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53678688, COSV53679874; called by muse, mutect2
- SEMG1 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.874); catalogued as COSV54873326; called by muse, mutect2, varscan2
- SLC25A11 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52591120; called by muse, mutect2, varscan2
- SPRY3 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 115/333 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746190550, COSV57143419; called by muse, mutect2, varscan2
- SPTAN1 | c.7271T>A p.V2424E | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV63988171; called by muse, mutect2
- TENT5D | c.1078A>T p.R360W | Missense Mutation (SNP) | VAF 67/81 reads (83%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as COSV57637223; called by muse, mutect2, varscan2
- TMC6 | c.1076T>G p.V359G | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59809534; called by muse, mutect2, varscan2
- TRIM38 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | catalogued as rs557556364, COSV62642380; called by muse, mutect2, varscan2
- TRPA1 | c.2438C>T p.T813M | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs538354055, COSV51564490; called by muse, mutect2, varscan2
- UNC45B | c.1600G>A p.G534S | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52096950; called by muse, mutect2, varscan2
- WDR90 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770923026, COSV53471231; called by muse, mutect2, varscan2
- ZNF91 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as COSV56087224; called by muse, mutect2, varscan2
- IGHV3-23 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 67/451 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- MST1 | c.820_823del p.R274Sfs*251 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by pindel, varscan2
- GDPD4 | c.1074C>T p.I358= | Silent (SNP) | VAF 57/186 reads (31%) | catalogued as rs766657500, COSV60020158; called by muse, mutect2, varscan2
- GRM5 | c.1209C>T p.A403= | Silent (SNP) | VAF 82/173 reads (47%) | catalogued as COSV59610227; called by muse, varscan2
- MDM1 | c.798G>A p.R266= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV57447043; called by muse, mutect2, varscan2
- NPTX2 | c.882C>T p.N294= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs149672697; called by muse, mutect2, varscan2
- PCLO | c.1962G>A p.P654= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs377565205; called by muse, mutect2, varscan2
- POM121L12 | c.27C>T p.S9= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs781474332, COSV68693243; called by muse, mutect2, varscan2
- RALGAPA1 | c.1260A>G p.L420= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs1567135792, COSV51886615; called by muse, mutect2, varscan2
- RGL3 | c.621G>A p.P207= | Silent (SNP) | VAF 142/634 reads (22%) | catalogued as rs752404115, COSV62698219; called by muse, mutect2, varscan2
- RPTOR | c.1113G>A p.P371= | Silent (SNP) | VAF 98/264 reads (37%) | catalogued as rs746590620, COSV60810507, COSV60819889; called by muse, mutect2, varscan2
- TMEM102 | c.915T>A p.A305= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV53440130; called by muse, mutect2, varscan2
- TSPYL6 | c.144G>C p.V48= | Silent (SNP) | VAF 78/215 reads (36%) | catalogued as COSV57816835; called by muse, mutect2, varscan2
- HERC2P3 | n.494G>A | RNA (SNP) | VAF 6/36 reads (17%) | catalogued as rs1203339480; called by mutect2, varscan2
- HLA-F | chr6:29726899 C>T | 3'Flank (SNP) | VAF 41/268 reads (15%) | catalogued as rs778687923, COSV52576283; called by muse, mutect2, varscan2
